Somatic mutation profile of tumor specimen BA2769D (aliquot aq-BA2769D) from BEATAML1.0 case 2482, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.4 years (26,454 days).
Specimen BA2769D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08ccfded-f4b5-42ed-9fc9-cfd1f6022182.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2061D (Solid Tissue Normal), aliquot aq-BA2061D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c344e009-a0bf-4ead-9fb4-486dd096c71e

The open-access MAF lists 27 somatic variants for this specimen: 18 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 8, Nonsense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RUNX1 | c.877C>T p.R293* (on ENST00000344691 / NM_001001890.3; = p.R320* on NM_001754.5) | Nonsense Mutation (SNP) | VAF 37/147 reads (25%) | catalogued as rs1569008655, CM086912, COSV55867803; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATG4C | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs146646910; called by muse, mutect2, varscan2
- DIAPH2 | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs41300144, COSV61294487; called by muse, mutect2, varscan2
- DSCAM | c.533C>T p.T178M | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.197); catalogued as rs200160585, COSV68643333; called by muse, mutect2, varscan2
- KCNJ15 | c.458C>T p.T153M | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1426563684; called by muse, mutect2
- LAMB2 | c.4522G>T p.A1508S | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV59736124; called by muse, mutect2
- MINAR2 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs777994154; called by muse, mutect2, varscan2
- PIGG | c.587C>A p.T196K | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56317201; called by muse, mutect2
- RUNX1 | c.538C>T p.R180W (on ENST00000344691 / NM_001001890.3; = p.R207W on NM_001754.5) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1555890007, COSV55897170, COSV55897913; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF628 | c.570C>A p.N190K | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV99219793; called by muse, mutect2
- ANKLE1 | c.679C>A p.Q227K (on ENST00000394458; = p.Q173K on NM_152363.6) | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.036); called by muse, mutect2
- CLTC | c.3045C>A p.N1015K | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.6); called by muse, mutect2
- FAM124A | c.597C>A p.S199R (on ENST00000322475 / NM_001242312.2; = p.S235R on NM_145019.4) | Missense Mutation (SNP) | VAF 10/298 reads (3%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.865); called by muse, mutect2
- FBXO34 | c.2076C>A p.H692Q | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.641); called by muse, mutect2
- TASOR2 | c.668G>A p.S223N | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TLR3 | c.365G>A p.C122Y | Missense Mutation (SNP) | VAF 46/236 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRPC6 | c.79G>T p.E27* | Nonsense Mutation (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- UBR4 | c.4651G>T p.A1551S | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.176); called by muse, mutect2
- BEX5 | c.63C>T p.P21= | Silent (SNP) | VAF 26/50 reads (52%) | called by muse, mutect2, varscan2
- EEF1A2 | c.786G>T p.V262= | Silent (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- FGF9 | c.228C>A p.I76= | Silent (SNP) | VAF 6/85 reads (7%) | called by muse, mutect2
- PCDHGB1 | c.2304G>A p.P768= | Silent (SNP) | VAF 68/315 reads (22%) | catalogued as rs1356070450; called by muse, mutect2, varscan2
- PRR23A | c.447C>T p.I149= | Silent (SNP) | VAF 36/100 reads (36%) | catalogued as COSV67214180; called by muse, mutect2, varscan2
- SLC6A14 | c.57G>A p.S19= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs781887297; called by muse, mutect2, varscan2
- SPON1 | c.972C>T p.P324= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as rs552457223, COSV100116809; called by muse, mutect2, varscan2
- STXBP3 | c.90C>T p.G30= | Silent (SNP) | VAF 28/139 reads (20%) | catalogued as rs368365634, COSV64182754; called by muse, mutect2, varscan2
- ADORA2A | c.-274-1626C>A | Intron (SNP) | VAF 5/43 reads (12%) | catalogued as rs994723107; called by muse, mutect2
